Surgical pathology report (de-identified scan), TCGA case TCGA-30-1860, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1860-01A (Primary Tumor).

[page 1 of 2]
Accession Number: [REDACTED]

Report Status: Final

Type: Surgical Pathology

Pathology Report [REDACTED] SOFT TISSUE BIOPSY

Accessioned On: [REDACTED]

DIAGNOSIS:

SPECIMEN LABELED "IMPLANT SMALL BOWEL MESENTERY":
POORLY DIFFERENTIATED CARCINOMA.

TCGA-30-1860

SPECIMEN LABELED "OMENTUM":

POORLY DIFFERENTIATED CARCINOMA, consistent with Adenocarcinoma, with extensive necrosis. See note.
Lymphovascular invasion is present.

Immunohistochemistry performed at [REDACTED] demonstrates the following staining profile in tumor cells:

Positive - Cytokeratin 7 (strong), [REDACTED]

Negative - Cytokeratin 20, [REDACTED]

NOTE: The tumor is characterized by sheets of poorly differentiated cells with rare glands. No papillary architecture or psammous calcifications are present. The histologic appearances and immunohistologic characteristics would be consistent with a breast or a mullerian-related primary.

SPECIMEN LABELED "NODULES FROM SMALL BOWEL" (Incl. FSA):
POORLY DIFFERENTIATED CARCINOMA.

SPECIMEN LABELED "NODULES FROM SMALL BOWEL":
POORLY DIFFERENTIATED CARCINOMA.

CLINICAL DATA:

History: [REDACTED] with family history of breast cancer and large pelvic mass, periaortic lymph adenopathy on MRI.

TISSUE SUBMITTED: 1. Implant small bowel mesenteric
2. Omentum
3. Nodules from small bowel [REDACTED]
4. Nodules from small bowel [REDACTED]

O.R. CONSULTATION:

SPECIMEN LABELED "#3 NODULES FROM SMALL BOWEL [REDACTED]
Poorly differentiated carcinoma, favor adenocarcinoma.

GROSS DESCRIPTION:

The specimen is received fresh, in 4 parts, each labeled with the patient's name and unit number.

Part, labeled "implant small bowel mesentery", consists of a 0.6 x 0.5 x 0.2 cm firm, tan tissue fragment.

Micro 2 - 1 frag, [REDACTED]

Part 2, "omentum", consists of a 23.5 x 12.9 x 3.5 cm sheet of omental fat. Approximately 40% of the specimen is diffusely replaced by firm, white tumor. The remainder consists predominantly of yellow/tan adipose tissue and is studded by multiple firm, white tumor nodules measuring up to 1.4 x 1 x 1 cm.

Micro 3-5 - omentum, 3 frags, [REDACTED]

Part 3, "nodules from small bowel", consists of two soft tan tissue fragments (1.0 x 0.6 x 0.5 cm) which are submitted for frozen section as [REDACTED]

Micro 6 - FSA remnant, 2 frags, [REDACTED]

Part 4, "nodules from small bowel", consists of seven soft tan, irregular,

[page 2 of 2]
nodular portions of tissue which measure from 0.4 x 0.3 x 0.3 cm to 0.7 x 0.6 x 0.5 cm. Two sections are placed in the cytogenetic media for potential flow cytometry, one section is placed in EM fixative for possible electron microscopy and one section is fixed in B5. The remainder is fixed in formalin.

Micro 1 - nodule from small bowel, B5 fixative
Micro 7 - nodules from small bowel, 3 frags,

tim

TCGA-30-1860

Reports to:

SPECIMEN TYPE: SOFT TISSUE BIOPSY
ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION
ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY
ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

Source: NCI Genomic Data Commons file 39599fb0-b8f7-420a-902f-01a69af20d15 (TCGA-30-1860.D5B8E59F-1AE5-4E22-B933-48E48A364788.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).